Gene-level copy-number profile of tumor specimen TCGA-UW-A72P-01A from TCGA case TCGA-UW-A72P, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 61.0 years (22,295 days).
Specimen TCGA-UW-A72P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4979ad1-2983-41bd-a574-d63c5adcaa2e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-UW-A72P-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/461e9dd3-3f08-449f-879e-58c285437195

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 18,904; copy number 2: 39,472; copy number 3: 6.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,565,828–87,566,764, 1 gene (within-gene range 0–1): PAFAH1B1P1.
- chr2:113,437,691–113,515,488, 3 genes: CBWD2, FOXD4L1, LINC01961.
- chr2:130,036,958–130,129,222, 6 genes (within-gene range 0–1): KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr17:46,274,784–46,579,691, 9 genes: ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 18,904. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
